Somatic mutation profile of tumor specimen BA3318D (aliquot aq-BA3318D) from BEATAML1.0 case 2593, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 83.1 years (30,347 days).
Specimen BA3318D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47b00cad-39c9-415c-97e0-56d0f54e4873.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3340D (Solid Tissue Normal), aliquot aq-BA3340D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5cd4aa8-7856-4fb1-b831-b804c1f2a087

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 93/165 reads (56%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs121913503, COSV57468734, COSV57468971, COSV57472976; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- CARD14 | c.559C>T p.H187Y | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.747); catalogued as rs1029810669; called by muse, mutect2, varscan2
- DNMT3A | c.2306T>A p.I769N | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746704362; called by muse, mutect2, varscan2
- ITPR1 | c.5942A>G p.N1981S (on ENST00000354582; = p.N1926S on NM_002222.7) | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1398402838; called by muse, mutect2, varscan2
- PHF6 | c.448G>T p.E150* (on ENST00000332070 / NM_032458.3; = p.E151* on NM_032335.3) | Nonsense Mutation (SNP) | VAF 63/138 reads (46%) | called by muse, mutect2, varscan2
- STAG2 | c.3383_3384del p.E1128Afs*7 | Frame Shift Del (DEL) | VAF 62/195 reads (32%) | called by pindel, varscan2
- SLC5A4 | c.1011C>T p.I337= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as rs758345767; called by muse, mutect2, varscan2
